Gene-level copy-number profile of tumor specimen TCGA-HU-A4GU-01A from TCGA case TCGA-HU-A4GU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.0 years (27,024 days).
Specimen TCGA-HU-A4GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.30f6ccab-ce99-4787-82a6-d151809c9d92.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4GU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa57a93a-bc98-4e88-9abf-d73505857b93

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,467; copy number 2: 25,792; copy number 3: 24,150; copy number 4: 5,500; copy number 5: 1,163; copy number 6: 581; copy number 7: 29; copy number 9: 6; copy number 10: 49; copy number 14: 51; copy number 19: 20; copy number 27: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4GU-01A-11D-A253-01): tumor purity 0.76, ploidy 2.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,690,225–60,690,719, 1 gene: PPIAP70.
- chr16:78,793,584–78,796,362, 1 gene: AC009141.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 160 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:89,443,946–93,928,610, 71 genes, copy number 10–19 (broad region; genes not listed).
- chr8:86,214,063–88,328,025, 23 genes, copy number 7 (within-gene range 5–7): SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16.
- chr10:1,957,589–2,936,441, 14 genes, copy number 19–27: AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1.
- chr10:13,643,706–14,462,142, 1 gene, copy number 10 (within-gene range 4–10): FRMD4A.
- chr10:13,991,815–15,719,922, 32 genes, copy number 10: AC044781.1, AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265, FAM107B, AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C, MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1, FAM171A1, AL607028.1, ITGA8.
- chr10:81,136,540–83,764,464, 13 genes, copy number 9–14: RPA2P2, AL096706.1, NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P, RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P.
- chr21:31,706,555–32,197,813, 6 genes, copy number 7: HMGN1P2, AP000255.1, TPT1P1, HUNK, HUNK-AS1, LINC00159.

Autosomal genes at a single copy (total copy number 1): 2,273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
